Somatic mutation profile of tumor specimen TCGA-13-2057-01A (aliquot TCGA-13-2057-01A-02D-1526-09) from TCGA case TCGA-13-2057, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 59.0 years (21,554 days).
Specimen TCGA-13-2057-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22d17dbe-86c7-4f99-a6d6-c69e0e925f00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-2057-10A (Blood Derived Normal), aliquot TCGA-13-2057-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a85c1b5d-04fe-43a1-a684-592413999d08

The open-access MAF lists 213 somatic variants for this specimen: 154 protein-altering or splice-affecting, 57 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 57, Nonsense Mutation 11, Splice Site 3, Frame Shift Del 2, Intron 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 176/200 reads (88%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCF1 | c.1964G>T p.C655F (on ENST00000326195 / NM_001025091.2; = p.C617F on NM_001090.3) | Missense Mutation (SNP) | VAF 40/963 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV100400789; called by muse, mutect2
- ACSS3 | c.1741G>C p.V581L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV54087564, COSV99698894; called by muse, mutect2, varscan2
- ADAM15 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 208/377 reads (55%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); catalogued as COSV55125884; called by muse, mutect2, varscan2
- ADNP2 | c.785A>G p.K262R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV51537269; called by muse, mutect2, varscan2
- AFF1 | c.1319C>A p.T440N | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV57118270; called by muse, mutect2, varscan2
- ANKRD44 | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051733611, COSV56557885, COSV99984625; called by muse, mutect2
- APOA2 | c.143T>G p.L48R | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99248185; called by muse, mutect2
- APOB | c.4318G>T p.V1440L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV51929161; called by muse, mutect2, varscan2
- AR | c.2599G>C p.V867L | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.295); catalogued as CM890012, CM920100, COSV65954254, COSV65954457; called by muse, mutect2, varscan2
- ARHGEF1 | c.370C>G p.R124G | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61526868; called by muse, mutect2, varscan2
- ARHGEF7 | c.2414G>T p.S805I (on ENST00000646102 / NM_001354046.1; = p.S589I on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 132/628 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV54540663; called by muse, mutect2, varscan2
- ARPP21 | c.1623G>T p.M541I | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV51794501; called by muse, mutect2, varscan2
- ATP2C1 | c.934A>T p.I312F | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60754560; called by muse, mutect2, varscan2
- BIN1 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 37/374 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV52117051; called by muse, mutect2
- BRD8 | c.1078A>G p.I360V (on ENST00000254900 / NM_139199.2; = p.I433V on NM_006696.4) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.946); catalogued as rs1405309931, COSV99136799; called by muse, mutect2
- BRWD3 | c.4901A>T p.D1634V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV64745644; called by muse, mutect2, varscan2
- C1QL4 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 18/481 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV57744270; called by muse, mutect2
- C6 | c.2224T>A p.S742T | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.068); catalogued as COSV54707480; called by muse, mutect2, varscan2
- CACNG6 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 98/480 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.444); catalogued as COSV53166126; called by muse, varscan2
- CCDC90B | c.741G>C p.L247F | Missense Mutation (SNP) | VAF 40/225 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52623632; called by muse, mutect2, varscan2
- CD163L1 | c.1756G>T p.V586L | Missense Mutation (SNP) | VAF 42/594 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs757847816, COSV100549930, COSV58011546; called by muse, mutect2
- CD86 | c.704-1G>C p.X235_splice (on ENST00000330540 / NM_175862.5; = p.X229_splice on NM_006889.4) | Splice Site (SNP) | VAF 40/461 reads (9%) | catalogued as COSV100053906, COSV52605464, COSV52608741; called by muse, mutect2
- CD8B | c.688A>G p.T230A (on ENST00000331469 / NM_172213.4; = p.T200A on NM_172102.4) | Missense Mutation (SNP) | VAF 88/788 reads (11%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs755706334, COSV58925430; called by muse, mutect2, varscan2
- CEP128 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs780227517; called by muse, mutect2
- CHD1L | c.1862T>C p.I621T | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV100787405; called by muse, mutect2
- CHGA | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs757656588, COSV99381068; called by muse, mutect2
- CLEC9A | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 16/439 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV100191324; called by muse, mutect2
- COL1A1 | c.3591C>G p.D1197E | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.24); catalogued as COSV56803308; called by muse, mutect2, varscan2
- COPS6 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57995012; called by muse, mutect2, varscan2
- CPA6 | c.1091T>A p.V364E | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99913266; called by muse, mutect2
- CREB3 | c.425C>G p.P142R | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59205825; called by muse, mutect2, varscan2
- CSMD2 | c.8326C>G p.H2776D | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV99588537; called by muse, mutect2
- CTTNBP2NL | c.1307G>A p.R436H | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1000121557, COSV54743316; called by muse, mutect2
- DDX43 | c.1261A>T p.R421W | Missense Mutation (SNP) | VAF 14/455 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100943940; called by muse, mutect2
- DECR1 | c.839T>G p.L280R | Missense Mutation (SNP) | VAF 76/365 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55167651; called by muse, mutect2, varscan2
- DNAH9 | c.8048C>A p.A2683D | Missense Mutation (SNP) | VAF 32/336 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs545515591, COSV99305220; called by muse, mutect2
- DRC1 | c.1873G>T p.V625F | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV99717240; called by muse, mutect2, varscan2
- DTX2 | c.1793A>T p.D598V | Missense Mutation (SNP) | VAF 49/475 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56859763; called by muse, mutect2, varscan2
- EMSY | c.3465G>T p.M1155I | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV100595476, COSV58258529; called by muse, mutect2, varscan2
- ESYT2 | c.2726A>T p.D909V (on ENST00000613624; = p.D833V on NM_020728.3) | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV51749411; called by muse, mutect2, varscan2
- ESYT3 | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 70/538 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56679975; called by muse, mutect2, varscan2
- FABP7 | c.284T>G p.I95R | Missense Mutation (SNP) | VAF 26/273 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100737933; called by muse, mutect2
- FAM117B | c.1746A>C p.E582D | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.099); catalogued as COSV100287378; called by muse, mutect2
- FAM83B | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60920622; called by muse, mutect2, varscan2
- FARS2 | c.1226A>G p.K409R | Missense Mutation (SNP) | VAF 51/423 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51165491; called by muse, mutect2, varscan2
- FAXC | c.995C>G p.P332R | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101067111; called by muse, mutect2
- FCGR3B | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.795); catalogued as COSV54209355; called by muse, mutect2, varscan2
- FGF9 | c.449C>A p.S150* | Nonsense Mutation (SNP) | VAF 26/146 reads (18%) | catalogued as COSV66644291; called by muse, mutect2, varscan2
- GLDC | c.2797A>T p.I933F | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58676511; called by muse, mutect2, varscan2
- GLIPR1L2 | c.603A>C p.R201S | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV57553581; called by muse, mutect2, varscan2
- GLIS3 | c.1210A>T p.R404* | Nonsense Mutation (SNP) | VAF 79/340 reads (23%) | catalogued as COSV60926577; called by muse, mutect2, varscan2
- GLYATL1 | c.523G>T p.D175Y (on ENST00000317391 / NM_001354699.1; = p.D206Y on NM_080661.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as COSV55607911, COSV55611658; called by muse, mutect2, varscan2
- GMIP | c.773A>T p.E258V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99179158; called by muse, mutect2
- GPC5 | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 28/49 reads (57%) | catalogued as COSV100996361, COSV65586658; called by muse, mutect2, varscan2
- GPRASP1 | c.134A>T p.Q45L | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100850966; called by muse, mutect2
- HEMGN | c.1163C>T p.T388I | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as rs201229826, COSV52325699; called by muse, mutect2, varscan2
- HMGB3 | c.271A>T p.N91Y | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57485706; called by muse, mutect2, varscan2
- HTRA4 | c.966+1G>A p.X322_splice | Splice Site (SNP) | VAF 47/266 reads (18%) | catalogued as rs781612001, COSV100205698; called by muse, mutect2, varscan2
- ILVBL | c.740A>G p.N247S | Missense Mutation (SNP) | VAF 13/225 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs1191867162, COSV99654744; called by muse, mutect2
- IMPG1 | c.1054G>C p.A352P | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as COSV100886664, COSV64055764; called by muse, mutect2, varscan2
- LAG3 | c.949A>G p.T317A | Missense Mutation (SNP) | VAF 33/488 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV52567787, COSV99179910; called by muse, mutect2
- MAGEA4 | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 64/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52340751; called by muse, mutect2, varscan2
- MAGEE1 | c.1862T>C p.F621S | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63909362; called by muse, mutect2, varscan2
- MAP1LC3C | c.52A>T p.S18C | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV61803575; called by muse, mutect2, varscan2
- MEFV | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV54819943; called by muse, mutect2, varscan2
- MEIS3 | c.164G>T p.R55M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100520409; called by muse, mutect2
- MLLT10 | c.2018A>T p.N673I (on ENST00000307729 / NM_001195626.3; = p.N689I on NM_004641.3) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100307935, COSV56993274; called by muse, mutect2, varscan2
- MS4A2 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99627181; called by muse, mutect2
- MTF2 | c.1507C>G p.L503V | Missense Mutation (SNP) | VAF 6/180 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.087); catalogued as COSV64771767; called by muse, mutect2
- MYH1 | c.5326G>T p.E1776* | Nonsense Mutation (SNP) | VAF 79/462 reads (17%) | catalogued as COSV56845648, COSV56845695; called by muse, mutect2, varscan2
- N6AMT1 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58134055; called by muse, mutect2, varscan2
- NACC2 | c.1310C>A p.A437D | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53199613; called by muse, mutect2, varscan2
- NCOA7 | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 33/362 reads (9%) | SIFT tolerated (0.5); PolyPhen benign (0.359); catalogued as COSV57657379; called by muse, mutect2
- NDN | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs1454287617, COSV59359037; called by muse, mutect2, varscan2
- NDRG2 | c.550C>T p.H184Y (on ENST00000298687 / NM_001354570.1; = p.H170Y on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/504 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.809); catalogued as rs1441110957, COSV100068954; called by muse, mutect2
- NEPRO | c.933T>A p.D311E | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100074988; called by muse, mutect2
- NFKBIB | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58003225; called by muse, mutect2, varscan2
- NKAPL | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); catalogued as rs756166058, COSV59197490; called by muse, mutect2
- NLRP2 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.015); catalogued as rs755024903, COSV99672146; called by muse, mutect2, varscan2
- NNT | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 33/223 reads (15%) | catalogued as COSV52923834, COSV99239300; called by muse, mutect2, varscan2
- NOL10 | c.1483C>G p.Q495E | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.405); catalogued as COSV100630008, COSV62041631; called by muse, mutect2
- NSUN6 | c.22T>C p.S8P | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.203); catalogued as COSV66032363; called by muse, mutect2, varscan2
- NT5DC3 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV67321491; called by muse, mutect2, varscan2
- NUP153 | c.3350T>A p.V1117D | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV50447390; called by muse, mutect2, varscan2
- OR4X2 | c.832A>C p.I278L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56582792; called by muse, mutect2, varscan2
- OR52N5 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1205903471, COSV100399659; called by muse, mutect2, varscan2
- OR6C4 | c.665C>A p.T222N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV101263144; called by muse, mutect2
- OR8H1 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.394); catalogued as COSV57293500; called by muse, mutect2, varscan2
- P2RX3 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 94/1018 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV99554857; called by muse, mutect2
- PCDHB4 | c.1631C>T p.A544V | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as COSV52020912; called by muse, varscan2
- PDE1C | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV100372033; called by muse, mutect2
- PGBD2 | c.18-1G>T p.X6_splice | Splice Site (SNP) | VAF 23/275 reads (8%) | catalogued as COSV100251972; called by muse, mutect2
- PHF2 | c.3038C>T p.P1013L | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs762832118, COSV63679830; called by muse, mutect2, varscan2
- PIK3CB | c.1832A>T p.D611V | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56684358; called by muse, mutect2, varscan2
- PIWIL2 | c.2878C>G p.H960D | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV63250482; called by muse, mutect2, varscan2
- PLCG1 | c.1722C>G p.I574M | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs146548575, COSV54821912; called by muse, mutect2, varscan2
- PLPP6 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 54/287 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.061); catalogued as COSV56304845; called by muse, mutect2, varscan2
- POLRMT | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV101627696; called by muse, mutect2
- POU3F3 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as rs1462775136, COSV63721412; called by muse, mutect2
- PPAT | c.1537G>C p.V513L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.056); catalogued as COSV51703492; called by muse, mutect2, varscan2
- PPP1R3F | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV50017890; called by muse, mutect2, varscan2
- PPP6R2 | c.1335C>T p.H445= | Splice Region (SNP) | VAF 29/77 reads (38%) | catalogued as COSV53291538; called by muse, mutect2, varscan2
- PRAMEF14 | c.1205G>A p.S402N | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs1189991248, COSV58049623; called by muse, mutect2, varscan2
- PRAMEF4 | c.554A>T p.K185M | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52437821; called by muse, mutect2, varscan2
- PRMT2 | c.842T>G p.V281G | Missense Mutation (SNP) | VAF 60/268 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV52454650; called by muse, mutect2, varscan2
- PRPSAP2 | c.88T>G p.S30A | Missense Mutation (SNP) | VAF 130/168 reads (77%) | SIFT tolerated (0.6); PolyPhen benign (0.02); catalogued as COSV52065132; called by muse, mutect2, varscan2
- PRRC2A | c.2701A>T p.K901* | Nonsense Mutation (SNP) | VAF 46/200 reads (23%) | catalogued as COSV65685804; called by muse, mutect2, varscan2
- PTH1R | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs201315349, COSV57314928; called by muse, mutect2, varscan2
- RASD2 | c.375C>G p.N125K | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.882); catalogued as COSV53352211; called by muse, mutect2, varscan2
- REN | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 64/449 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145852603; called by mutect2, varscan2
- RNF149 | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54863067, COSV54863373; called by muse, mutect2, varscan2
- RPTOR | c.3551G>C p.G1184A | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60805560; called by muse, mutect2, varscan2
- SAMD3 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 25/117 reads (21%) | catalogued as COSV60774959, COSV60775188; called by muse, mutect2, varscan2
- SEL1L | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV60919691; called by muse, mutect2, varscan2
- SFTPA2 | c.543C>G p.Y181* | Nonsense Mutation (SNP) | VAF 118/339 reads (35%) | catalogued as COSV100958732; called by muse, mutect2, varscan2
- SHANK2 | c.2056A>T p.I686F | Missense Mutation (SNP) | VAF 67/607 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV53608045, COSV99573225; called by muse, mutect2, varscan2
- SIN3B | c.965A>C p.E322A | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.733); catalogued as COSV99931593; called by muse, mutect2
- SLC12A7 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 43/194 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs200454360, COSV53755680; called by muse, mutect2, varscan2
- SLC22A9 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV54165973, COSV54166414; called by muse, mutect2, varscan2
- SLC25A52 | c.397G>A p.V133M (on ENST00000672005; = p.V123M on NM_001034172.4) | Missense Mutation (SNP) | VAF 24/248 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as rs187699626, COSV52504731; called by muse, mutect2
- SLC27A2 | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51058136; called by muse, mutect2, varscan2
- SLC8A3 | c.2284A>G p.I762V (on ENST00000381269 / NM_183002.3; = p.I760V on NM_033262.4) | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV53688334; called by muse, mutect2, varscan2
- SLC9C2 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV62944645; called by muse, mutect2, varscan2
- SNTG1 | c.215T>C p.I72T | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV52433251; called by muse, mutect2, varscan2
- SNURF | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.018); catalogued as COSV57595021; called by muse, mutect2, varscan2
- SOCS5 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV60604139; called by muse, mutect2, varscan2
- SORL1 | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV52751569; called by muse, mutect2, varscan2
- SPPL3 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 178/215 reads (83%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV62231771; called by muse, mutect2, varscan2
- TCF20 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.655); catalogued as rs1289771903, COSV59489454; called by muse, mutect2, varscan2
- TCF23 | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV56078144; called by muse, mutect2, varscan2
- TDRD6 | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs1258662650, COSV60174695; called by muse, mutect2, varscan2
- TEX55 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV99817442; called by muse, mutect2
- TMX2 | c.305C>G p.T102R | Missense Mutation (SNP) | VAF 34/278 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV53553718; called by muse, mutect2, varscan2
- TNC | c.3529G>C p.G1177R | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.606); catalogued as COSV60782824; called by muse, mutect2, varscan2
- TNFRSF21 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1378753518, COSV57280919; called by muse, mutect2, varscan2
- TP53TG5 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as COSV65577133, COSV65577320, COSV65577985; called by muse, mutect2, varscan2
- TRIM50 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782766082, COSV53090983; called by muse, mutect2, varscan2
- TRPM2 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 96/467 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772629307, COSV55967678; called by muse, mutect2, varscan2
- UBTF | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV100255868, COSV57189042; called by muse, mutect2
- URB2 | c.2197C>T p.L733F | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.215); catalogued as COSV50983319; called by muse, mutect2, varscan2
- VASP | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 45/657 reads (7%) | catalogued as COSV99840930; called by muse, mutect2
- VPS13A | c.5994A>G p.I1998M | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs1368944545, COSV100652494; called by muse, mutect2
- VWF | c.343T>G p.S115A | Missense Mutation (SNP) | VAF 24/412 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV99778676; called by muse, mutect2
- WASF3 | c.1363A>G p.K455E | Missense Mutation (SNP) | VAF 59/282 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV58963930; called by muse, mutect2, varscan2
- ZFP14 | c.1091G>C p.G364A | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54201624; called by muse, mutect2, varscan2
- ZNF462 | c.103G>T p.D35Y | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV52933834; called by muse, mutect2, varscan2
- ZNF596 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.159); catalogued as COSV57653283; called by muse, mutect2, varscan2
- ZNF623 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 63/254 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV71697128; called by muse, mutect2, varscan2
- ZNF711 | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); catalogued as COSV99340894; called by muse, mutect2
- ZSCAN4 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as COSV56591926; called by muse, mutect2, varscan2
- ATXN2 | c.2981_2983delinsACATAT p.A994_K995delinsDI* (on ENST00000550104; = p.A834_K835delinsDI* on NM_002973.4) | Nonsense Mutation (INS) | VAF 59/383 reads (15%) | called by pindel, varscan2*
- DENND4C | c.3920_3921del p.E1307Gfs*34 (on ENST00000434457 / NM_001330640.2; = p.E1258Gfs*34 on NM_017925.7) | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | called by pindel, varscan2
- HEATR5B | c.4273del p.A1425Lfs*10 | Frame Shift Del (DEL) | VAF 25/241 reads (10%) | called by mutect2, pindel, varscan2
- AGO2 | c.1740C>A p.P580= | Silent (SNP) | VAF 28/304 reads (9%) | catalogued as COSV99595538; called by muse, mutect2, varscan2
- ALPI | c.276C>T p.R92= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV99785817; called by muse, mutect2
- ALPK1 | c.258C>T p.A86= | Silent (SNP) | VAF 56/298 reads (19%) | catalogued as rs770990158, COSV51583363; called by muse, varscan2
- ARHGAP4 | c.2241G>C p.G747= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV61685943; called by muse, mutect2, varscan2
- BRPF1 | c.2719A>C p.R907= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV57403925; called by muse, mutect2, varscan2
- CALR3 | c.954C>A p.I318= | Silent (SNP) | VAF 34/352 reads (10%) | catalogued as COSV99522128; called by muse, mutect2
- CDC42BPA | c.930G>T p.V310= | Silent (SNP) | VAF 16/155 reads (10%) | catalogued as COSV100504503; called by muse, mutect2, varscan2
- CGB1 | c.199C>T p.L67= | Silent (SNP) | VAF 22/155 reads (14%) | catalogued as rs1285197170, COSV100031591; called by muse, mutect2, varscan2
- COL5A2 | c.4191C>G p.A1397= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV66408307; called by muse, mutect2, varscan2
- COQ8A | c.792G>C p.V264= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV64656883; called by muse, mutect2, varscan2
- DAB2 | c.990G>A p.P330= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs199558080; called by muse, mutect2, varscan2
- EHMT1 | c.3138G>C p.V1046= | Silent (SNP) | VAF 70/330 reads (21%) | catalogued as COSV101509718, COSV71777481; called by muse, mutect2, varscan2
- EIF2AK2 | c.867C>T p.D289= | Silent (SNP) | VAF 20/217 reads (9%) | catalogued as rs2302799, COSV99240557; called by muse, mutect2
- ELK1 | c.693G>A p.S231= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV55952372; called by muse, mutect2, varscan2
- FAM114A2 | c.1509A>G p.L503= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV61077400; called by muse, mutect2, varscan2
- GBP1 | c.984G>A p.V328= | Silent (SNP) | VAF 57/617 reads (9%) | catalogued as COSV100976246; called by muse, mutect2
- GHRHR | c.165C>T p.C55= | Silent (SNP) | VAF 122/156 reads (78%) | catalogued as rs755430803, COSV58195974; called by muse, mutect2, varscan2
- GOPC | c.144G>A p.V48= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as COSV99270860; called by muse, mutect2
- GYS2 | c.2089C>T p.L697= | Silent (SNP) | VAF 50/837 reads (6%) | catalogued as COSV99679654; called by muse, mutect2
- HDAC5 | c.51G>A p.L17= | Silent (SNP) | VAF 72/490 reads (15%) | catalogued as COSV56817830, COSV99870891; called by muse, mutect2, varscan2
- HSD3B1 | c.103T>C p.L35= | Silent (SNP) | VAF 92/500 reads (18%) | catalogued as COSV52489996; called by muse, mutect2, varscan2
- KIF5A | c.1422A>G p.Q474= | Silent (SNP) | VAF 54/463 reads (12%) | catalogued as rs1373971092, COSV54052838; called by muse, mutect2, varscan2
- LILRA4 | c.372C>T p.T124= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs1299923631, COSV52491077; called by muse, mutect2, varscan2
- LPA | c.2652T>G p.P884= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV60299443; called by muse, mutect2
- LRRN3 | c.48C>T p.I16= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs772132406, COSV57818161; called by muse, mutect2, varscan2
- MAGED2 | c.57A>T p.S19= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as COSV54497326, COSV54498136; called by muse, mutect2, varscan2
- MDN1 | c.16560T>C p.N5520= | Silent (SNP) | VAF 16/170 reads (9%) | catalogued as COSV101021097; called by muse, mutect2
- MKRN3 | c.129T>C p.A43= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs1256521662, COSV58809274; called by muse, mutect2, varscan2
- MMP9 | c.615C>T p.D205= | Silent (SNP) | VAF 21/216 reads (10%) | catalogued as rs1164849527, COSV100812384; called by muse, mutect2
- MRPL53 | c.141C>G p.L47= | Silent (SNP) | VAF 35/357 reads (10%) | catalogued as COSV99252071; called by muse, mutect2
- MYH8 | c.2328G>C p.L776= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs930338536, COSV67962109; called by muse, mutect2, varscan2
- OR6C68 | c.762C>A p.I254= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV101110023; called by muse, mutect2
- OR8H3 | c.231C>A p.V77= | Silent (SNP) | VAF 175/652 reads (27%) | catalogued as COSV57908087; called by muse, mutect2, varscan2
- PLD2 | c.810G>A p.G270= | Silent (SNP) | VAF 38/279 reads (14%) | catalogued as rs1250687479, COSV54004651; called by muse, mutect2, varscan2
- POPDC2 | c.360G>A p.Q120= | Silent (SNP) | VAF 46/557 reads (8%) | catalogued as COSV99950937; called by muse, mutect2
- PSMD1 | c.1008G>A p.E336= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as rs1207329150, COSV100433491; called by muse, mutect2, varscan2
- PTPN11 | c.1527A>T p.A509= | Silent (SNP) | VAF 68/474 reads (14%) | catalogued as COSV61006983; called by muse, mutect2, varscan2
- PTPN21 | c.2298C>T p.D766= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as rs376146786; called by muse, mutect2, varscan2
- PXMP2 | c.582G>C p.G194= | Silent (SNP) | VAF 15/356 reads (4%) | catalogued as COSV100443500; called by muse, mutect2
- REV3L | c.7689G>A p.V2563= | Silent (SNP) | VAF 23/284 reads (8%) | catalogued as COSV100725090; called by muse, mutect2
- RFC5 | c.78C>T p.Y26= | Silent (SNP) | VAF 52/284 reads (18%) | catalogued as COSV57477108; called by muse, mutect2, varscan2
- RREB1 | c.2601C>T p.N867= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs769736395, COSV58559861; called by muse, mutect2
- SALL3 | c.1302G>A p.A434= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs768341115, COSV73305891; called by muse, mutect2, varscan2
- SERPINH1 | c.120G>A p.A40= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV100825047; called by muse, mutect2
- SH3BP4 | c.1593G>A p.L531= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs148242042; called by muse, mutect2, varscan2
- SHANK2 | c.2055G>A p.L685= | Silent (SNP) | VAF 66/612 reads (11%) | catalogued as COSV99573229; called by muse, mutect2, varscan2
- SLC22A6 | c.1026C>T p.L342= | Silent (SNP) | VAF 14/245 reads (6%) | catalogued as rs1258130382, COSV100842816; called by muse, mutect2
- SLC41A3 | c.1267C>T p.L423= | Silent (SNP) | VAF 40/261 reads (15%) | catalogued as COSV59987495; called by muse, mutect2, varscan2
- SLCO1C1 | c.1665T>C p.L555= | Silent (SNP) | VAF 28/612 reads (5%) | catalogued as COSV99858894; called by muse, mutect2
- SLITRK3 | c.1908A>T p.P636= | Silent (SNP) | VAF 9/136 reads (7%) | catalogued as COSV99578918; called by muse, mutect2
- TMEM89 | c.267G>T p.R89= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs1243996387, COSV56570632; called by muse, mutect2, varscan2
- TNXB | c.11532C>T p.P3844= (on ENST00000647633; = p.P3597= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/229 reads (11%) | catalogued as COSV64475980; called by muse, mutect2, varscan2
- TRPM2 | c.726C>T p.A242= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs1233588825, COSV55967671; called by muse, mutect2, varscan2
- VNN3 | c.144A>G p.E48= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV99258196; called by muse, mutect2
- XPNPEP2 | c.1821T>C p.S607= | Silent (SNP) | VAF 42/337 reads (12%) | catalogued as COSV64368623; called by muse, mutect2, varscan2
- ZNF414 | c.918G>A p.A306= | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as COSV99726495; called by muse, mutect2
- ZSWIM3 | c.81C>T p.S27= | Silent (SNP) | VAF 45/341 reads (13%) | catalogued as rs748364577, COSV54168838; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039642 G>A | 5'Flank (SNP) | VAF 54/189 reads (29%) | called by muse, mutect2, varscan2
- USH1C | c.1285-7450T>C | Intron (SNP) | VAF 24/151 reads (16%) | catalogued as COSV50014888; called by muse, mutect2, varscan2
